Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16N-01A (Primary Tumor).

[page 1 of 7]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

for

Surgical Pathology

DIAGNOSIS:

A. Bladder peritoneum, biopsy: Metastatic adenocarcinoma consistent with endometrial primary.

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (6.6 x 6.1 x 5.5 cm) located in the fundus. The tumor

invades 1.1 cm into the myometrium (total myometrial wall thickness,

2.6 cm). Angiolymphatic invasion is present. The tumor does not

involve the endocervix or cervix. The cervix is unremarkable. The

left ovary is involved by metastatic endometrial adenocarcinoma

forming a 6.2 x 3.7 x 2.5 cm mass. The right ovary is involved by a

microscopic focus (0.3 cm) of metastatic endometrial adenocarcinoma.

The right and left ovarian surface is uninvolved. The right and

left fallopian tubes are without diagnostic abnormality.

C. Adnexal mass and portion of fallopian tube, right, excision:

Metastatic adenocarcinoma consistent with endometrial primary

forming a 5.0 x 3.8 x 3.0 cm adnexal mass. Portion of fallopian

tube is uninvolved.

D-G. Lymph nodes, left pelvic, excision: Multiple left pelvic

lymph nodes (5 external iliac, 2 internal iliac, 14 common iliac, 13

obturator) are negative for tumor.

H-K. Lymph nodes, right pelvic, excision: Multiple right pelvic

[page 2 of 7]
lymph nodes (7 external iliac, 3 internal iliac, 2 common iliac, 3 obturator) are negative for tumor.

L-M. Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

N-Q. Lymph nodes, right and left para-aortic above and below the inferior mesenteric artery, excisions: Multiple para-aortic lymph nodes above the inferior mesenteric artery (6 right, 1 left) are negative for tumor. Multiple para-aortic lymph nodes below the inferior mesenteric artery (2 right, 1 left) are negative for tumor.

R. Omentum, omentectomy: Mature adipose tissue; negative for tumor.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "bladder peritoneum" is a 3.0 x 2.2 x 0.6 cm aggregate of fibromembranous soft tissue with six nodules (ranging in size from 0.2 cm to 0.8 cm in greatest dimension).

Representative sections are submitted. Grossed by .

B. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 375.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa smooth

[page 3 of 7]
There is a 6.6 x 6.1 x 5.5 cm mass in the posterior uterine wall of the endometrial cavity with 2.6 cm myometrial thickness. Deepest extent of invasion by tumor appears to be 1.1 cm. There is a 3.0 x 2.8 x 2.0 cm right ovary with a smooth outer surface and a solid cut surface with a 5.5 x 0.5 cm right fallopian tube. There is a 6.2 x 3.7 x 2.5 cm left ovary with a smooth outer surface and a 5.2 x 3.2 x 2.5 cm solid and hemorrhagic mass with an 11.0 x 0.4 cm left fallopian tube. Representative sections submitted. Grossed by .

C. Received fresh labeled "right tubal nodule" is a 5.7 x 3.8 x 3.0 cm mass with a 3.5 x 0.5 cm attached fallopian tube. The mass has adherent adipose tissue. The cut surface is partially cystic and necrotic. Representative sections submitted

D. Received fresh labeled "left pelvic nodes internal" is a 2.0 x 1.5 x 0.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "left pelvic nodes external" is a 7.7 x 6.8 x 2.2 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "left pelvic nodes common" is a 3.7 x 2.8 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

G. Received fresh labeled "left pelvic nodes obturator" is a 6.8 x 4.3 x 2.7 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 4 of 7]
H. Received fresh labeled "right pelvic nodes internal" is a 6.0 x

3.6 x 1.1 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

I. Received fresh labeled "right pelvic nodes external" is a 9.0 x

6.5 x 1.5 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

J. Received fresh labeled "right pelvic nodes common" is a 5.0 x

3.6 x 1.5 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

K. Received fresh labeled "right pelvic nodes obturator" is a 7.2 x

4.0 x 2.0 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

L. Received fresh labeled "right gonadal vessel" is a 9.0 cm in

length by 0.5 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

M. Received fresh labeled "left gonadal vessel" is a 6.5 cm in

length by 0.5 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

N. Received fresh labeled "right para-aortic lymph nodes above the

IMA" is a 6.5 x 3.0 x 2.0 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

O. Received fresh labeled "right para-aortic lymph nodes below the

IMA" is a 4.6 x 3.0 x 2.0 cm aggregate of adipose and lymphatic

[page 5 of 7]
tissue. All lymphatic tissue submitted.

P. Received fresh labeled "left para-aortic lymph nodes above the

IMA" is a 4.6 x 4.5 x 2.0 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

Q. Received fresh labeled "left para-aortic lymph nodes below the

IMA" is a 5.0 x 3.0 x 2.0 cm aggregate of adipose and lymphatic

tissue. All lymphatic tissue submitted.

R. Received fresh labeled "omental biopsy" is a 14.0 x 10.0 x 4.0

cm portion of omentum. No masses are identified grossly. Lymph

nodes are not identified. Representative sections submitted.

BLOCK SUMMARY:

Part A: Bladder Peritoneum

1 Bladder peritoneum

Part B: Uterus, right and left fallopian tubes and ovaries

1 Cx 6:00

2 Endometrium

3 Endometrium

4 Uterus tumor

5 Uterus tumor

6 Low uterine segment

7 Uterus tumor

8 Uterus tumor

9 Uterus tumor

10 Uterus tumor

11 Left ovarian mass

12 Left ovary

13 Left fallopian tube

14 Right ovary

15 Right fallopian tube

Part C: Right tubal nodule

1 Rt fallopian tube with mass

2 Rt fallopian tube with mass

[page 6 of 7]
Part D: Left Pelvic Nodes: internal

- 1 Lt internal LNs 2
- 2 Lt internal fat

Part E: Left Pelvic Nodes: external

- 1 Lt external LN (1of4)
- 2 Lt external LN (2of4)
- 3 Lt external LN (3of4)
- 4 Lt external LN (4of4)
- 5 Lt external LNs 3
- 6 Lt external LNs 3
- 7 Lt external LN 1

Part F: Left Pelvic Nodes: common

- 1 Lt common LNs 3
- 2 Lt common LNs 5
- 3 Lt common LNs 5
- 4 Lt common LNs 2
- 5 Lt common LNs 2

Part G: Left Pelvic Nodes: obturator

- 1 Lt obturator LNs 4
- 2 Lt obturator LNs 3
- 3 Lt obturator LN 1
- 4 Lt obturator LN 1
- 5 Lt obturator LN (1of2)
- 6 Lt obturator LN (2of2)
- 7 Lt obturator LNs 3
- 8 Lt obturator LNs 2
- 9 Lt obturator LN 4
- 10 Lt obturator LNs (1of2)
- 11 Lt obturator LNs (2of2)
- 12 Lt obturator LNs 1

Part H: Right Pelvic Lymph Nodes internal

- 1 Rt internal LN 1
- 2 Rt internal LN 1

Part I: Right Pelvic Lymph Nodes external

- 1 Rt internal LNs 2
- 2 Rt internal LNs 2
- 3 Rt internal LN 1
- 4 Rt internal LN 1

Part J: Right Pelvic Lymph Nodes common

- 1 Rt common LN 1

[page 7 of 7]
2 Rt common LN 1

Part K: Right Pelvic Lymph Nodes obturator

1 Rt obturator LNs 3

Part L: Right Gonadal vessels

1 Rt gonadal vessels

2 Rt gonadal vessels

Part M: Left Gonadal vessels

1 Lt gonadal vessels

2 Lt gonadal vessels

Part N: Right Para-aortic Nodes above IMA

1 Rt above IMA LNs 2

2 Rt above IMA LNs (1of2)

3 Rt above IMA LNs (2of2)

4 Rt above IMA LNs (1of2)

5 Rt above IMA LNs (2of2)

Part O: Right Para-aortic Nodes below IMA

1 Rt below IMA LNs 1

Part P: Left Para-aortic Nodes above IMA

1 Lt above IMA LNs 1

Part Q: Left Para-aortic Nodes below IMA

1 Lt below IMA LNs (1of3)

2 Lt below IMA LNs (2of3)

3 Lt below IMA LNs (3of3)

Part R: Omental biopsy

1 Omental biopsy

2 Omental biopsy

3 Omental biopsy

4 Omental biopsy

Source: NCI Genomic Data Commons file 3d36b80e-811c-46d0-9dc8-4be3318b81e4 (TCGA-D1-A16N.81CFA07C-5FCE-41F3-88D1-FFD17840B293.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).